Somatic mutation profile of tumor specimen TCGA-AB-2912-03A (aliquot TCGA-AB-2912-03A-01W-0732-08) from TCGA case TCGA-AB-2912, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.9 years (23,345 days).
Specimen TCGA-AB-2912-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0aae0307-dcf0-43d6-8a6d-4610369fa93e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2912-11A (Solid Tissue Normal), aliquot TCGA-AB-2912-11A-01W-0761-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a83f6c6e-b41a-438c-9591-93fe486c7905

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.404G>A p.R135K (on ENST00000344691 / NM_001001890.3; = p.R162K on NM_001754.5) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1057519750, COSV55868310; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADSS2 | c.1070+1G>A p.X357_splice | Splice Site (SNP) | VAF 26/85 reads (31%) | catalogued as rs748168597, COSV63695634; called by muse, mutect2, varscan2
- BCAN | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1177410377, COSV61257927; called by muse, mutect2, varscan2
- DUSP26 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56361759; called by muse, mutect2, varscan2
- KCNU1 | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 23/130 reads (18%) | catalogued as rs567477009, COSV67757795; called by mutect2, varscan2
- OGDHL | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); catalogued as rs761031606, COSV100934251; called by muse, mutect2
- POC1A | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56592356; called by muse, mutect2, varscan2
- PUS1 | c.572A>T p.N191I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59035981; called by muse, mutect2, varscan2
- SCN3A | c.1435G>C p.G479R | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51815892; called by muse, mutect2, varscan2
- UQCC1 | c.393G>T p.E131D | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.277); catalogued as COSV62902964; called by muse, mutect2, varscan2
- BCORL1 | c.2714_2715insAGATCCCTCA p.N905Kfs*15 | Frame Shift Ins (INS) | VAF 13/23 reads (57%) | called by mutect2, pindel, varscan2
- CCDC33 | c.162C>T p.S54= | Silent (SNP) | VAF 31/295 reads (11%) | catalogued as rs368462763; called by muse, mutect2, varscan2
- ZFHX4 | c.7329A>T p.T2443= | Silent (SNP) | VAF 2/10 reads (20%) | called by mutect2, varscan2
